Somatic mutation profile of tumor specimen TCGA-BG-A0M0-01A (aliquot TCGA-BG-A0M0-01A-11W-A10C-09) from TCGA case TCGA-BG-A0M0, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 66.9 years (24,427 days).
Specimen TCGA-BG-A0M0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 395b727c-e3cb-4409-838a-0a87e1137dd5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0M0-10A (Blood Derived Normal), aliquot TCGA-BG-A0M0-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/915a92df-cc2a-4d8c-9ba0-cf7cd4d77b5b

The open-access MAF lists 168 somatic variants for this specimen: 132 protein-altering or splice-affecting, 35 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 35, Frame Shift Del 25, Nonsense Mutation 7, Frame Shift Ins 4, Splice Site 2, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 158/337 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as rs1064793732, CM126690, COSV55881636, COSV55977337; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 85/192 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1057519872, COSV55911123; ClinVar: not provided; called by muse, mutect2, varscan2
- VWF | c.2435dup p.M814Hfs*5 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | catalogued as rs62643632; ClinVar: pathogenic; called by pindel, varscan2
- ADAM23 | c.2340del p.K781Rfs*14 | Frame Shift Del (DEL) | VAF 67/199 reads (34%) | catalogued as rs767549806; called by mutect2, pindel, varscan2
- ADGRG4 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 82/172 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.502); catalogued as COSV54963855; called by muse, mutect2, varscan2
- AP4E1 | c.2837T>C p.V946A | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as COSV55919240; called by muse, mutect2, varscan2
- ARAF | c.619del p.L207Yfs*85 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as COSV51695741; called by mutect2, pindel, varscan2
- ASPH | c.2178G>T p.E726D | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57980752; called by muse, mutect2, varscan2
- ASPM | c.9577C>T p.R3193C | Missense Mutation (SNP) | VAF 130/438 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140679756; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATRX | c.3677T>C p.I1226T | Missense Mutation (SNP) | VAF 172/404 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV64881299; called by muse, mutect2, varscan2
- CACNB1 | c.132C>A p.S44R | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV59999835; called by muse, mutect2, varscan2
- CALN1 | c.80G>A p.S27N (on ENST00000329008 / NM_001017440.3; = p.S69N on NM_031468.4) | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.073); catalogued as rs1456431084, COSV61145307; called by muse, mutect2, varscan2
- CATSPERG | c.2807C>T p.T936I | Missense Mutation (SNP) | VAF 131/333 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53052228; called by muse, mutect2, varscan2
- CCDC190 | c.798G>T p.E266D | Missense Mutation (SNP) | VAF 97/309 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV63363387; called by muse, mutect2, varscan2
- CD177 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs1311884896, COSV65122244; called by muse, mutect2, varscan2
- CDK17 | c.1465A>G p.I489V | Missense Mutation (SNP) | VAF 100/213 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs200838762, COSV54132237; called by muse, mutect2, varscan2
- CGNL1 | c.2528G>A p.R843Q | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs150556311; called by muse, mutect2, varscan2
- CNTN6 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 107/261 reads (41%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as rs759512085, COSV63184405; called by muse, mutect2, varscan2
- CSMD3 | c.1360T>C p.F454L (on ENST00000297405 / NM_001363185.1; = p.F350L on NM_052900.3) | Missense Mutation (SNP) | VAF 182/243 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52276830; called by muse, mutect2, varscan2
- CTNNA2 | c.2260C>G p.R754G | Missense Mutation (SNP) | VAF 217/340 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV58144577, COSV58171085; called by muse, varscan2
- CYP4F22 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1419731471, COSV54107687; called by muse, mutect2
- DCAF12L2 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775259004, COSV63580943; called by muse, mutect2, varscan2
- DMD | c.9569G>A p.R3190Q | Missense Mutation (SNP) | VAF 160/353 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766768395, COSV58939355; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH7 | c.1037del p.K346Sfs*23 | Frame Shift Del (DEL) | VAF 69/181 reads (38%) | catalogued as rs761292636; called by mutect2, varscan2
- DNAH8 | c.4418del p.N1473Ifs*15 | Frame Shift Del (DEL) | VAF 60/146 reads (41%) | catalogued as rs778628413, COSV59486260; called by mutect2, varscan2
- DYNC1H1 | c.10745G>A p.R3582Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs866994746, COSV64136758; called by muse, mutect2, varscan2
- DYNC1I1 | c.649A>G p.T217A | Missense Mutation (SNP) | VAF 105/246 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV61468313; called by muse, mutect2, varscan2
- DYRK2 | c.1142C>T p.T381M (on ENST00000344096 / NM_006482.3; = p.T308M on NM_003583.4) | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757508984, COSV59847140; called by muse, mutect2, varscan2
- ELP4 | c.1266C>A p.H422Q (on ENST00000350638; = p.H421Q on NM_019040.5) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV63356965; called by muse, mutect2, varscan2
- EZHIP | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 8/11 reads (73%) | catalogued as COSV57957242; called by muse, mutect2, varscan2
- FAM120A | c.840C>G p.D280E | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.434); catalogued as COSV52908964, COSV52909382; called by muse, mutect2, varscan2
- FAP | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 122/297 reads (41%) | catalogued as COSV51865923; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 44/112 reads (39%) | catalogued as rs748969702; called by mutect2, varscan2
- GAB2 | c.1693C>T p.R565C (on ENST00000361507 / NM_080491.3; = p.R527C on NM_012296.3) | Missense Mutation (SNP) | VAF 141/363 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs1191816879, COSV60870186; called by muse, mutect2, varscan2
- GOLGB1 | c.9697C>T p.R3233W | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745651336, COSV58859217; called by muse, mutect2, varscan2
- HERC6 | c.2477G>A p.R826H | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs367814329; called by muse, varscan2
- HMCN1 | c.1480del p.E494Kfs*46 | Frame Shift Del (DEL) | VAF 92/339 reads (27%) | catalogued as COSV54928758; called by mutect2, pindel, varscan2
- IARS2 | c.962T>A p.V321E | Missense Mutation (SNP) | VAF 44/280 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV56962832; called by muse, mutect2, varscan2
- ICE2 | c.778C>T p.H260Y | Missense Mutation (SNP) | VAF 121/313 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs772036104, COSV55033379; called by muse, mutect2, varscan2
- IGSF21 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs748938162, COSV52127521; called by muse, mutect2, varscan2
- INPP4B | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs769344936, COSV53736899; called by muse, mutect2, varscan2
- IP6K3 | c.706A>G p.M236V | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs775163435, COSV53391393; called by muse, mutect2, varscan2
- IRF2BPL | c.2197G>A p.V733I | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs1167317350, COSV53148449; called by muse, mutect2, varscan2
- KAT7 | c.1198C>G p.R400G | Missense Mutation (SNP) | VAF 176/340 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52016281, COSV52016944; called by muse, mutect2, varscan2
- KIAA2026 | c.4225T>G p.S1409A | Missense Mutation (SNP) | VAF 364/868 reads (42%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as COSV67356974; called by muse, mutect2, varscan2
- KIF21A | c.176C>G p.S59C | Missense Mutation (SNP) | VAF 125/299 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100735170, COSV62776159; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 510/1122 reads (45%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LNPEP | c.434del p.N145Tfs*6 | Frame Shift Del (DEL) | VAF 40/102 reads (39%) | catalogued as rs748712732; called by mutect2, varscan2
- LRRC19 | c.595+2T>G p.X199_splice | Splice Site (SNP) | VAF 14/178 reads (8%) | catalogued as COSV66259736; called by muse, mutect2
- LYPLA2 | c.308T>A p.I103N | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65720938; called by muse, mutect2, varscan2
- MAP9 | c.1334G>A p.R445K | Missense Mutation (SNP) | VAF 240/618 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.147); catalogued as COSV60905913; called by muse, mutect2, varscan2
- MMP25 | c.1573C>A p.P525T | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.58); PolyPhen benign (0.018); catalogued as COSV60680799; called by mutect2, varscan2
- MRPL10 | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV51620950; called by muse, mutect2, varscan2
- MTERF1 | c.665G>A p.G222D | Missense Mutation (SNP) | VAF 106/238 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.095); catalogued as COSV61098930; called by muse, mutect2, varscan2
- MTMR11 | c.1437del p.W480Gfs*10 (on ENST00000439741 / NM_001145862.2; = p.W408Gfs*10 on NM_181873.3) | Frame Shift Del (DEL) | VAF 34/125 reads (27%) | catalogued as rs1559804082; called by mutect2, pindel, varscan2
- MUC15 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 152/373 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55554181; called by muse, mutect2, varscan2
- MUC16 | c.26413G>T p.D8805Y | Missense Mutation (SNP) | VAF 103/220 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.713); catalogued as COSV67479507; called by muse, mutect2, varscan2
- MYO18A | c.5047C>T p.R1683* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV62871691; called by muse, mutect2, varscan2
- NDUFAF6 | c.714+1G>A p.X238_splice | Splice Site (SNP) | VAF 160/703 reads (23%) | catalogued as rs1434721810, COSV54410189; called by muse, mutect2, varscan2
- NFASC | c.3221C>T p.T1074M | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs750684150, COSV58361685; called by muse, mutect2, varscan2
- NOP56 | c.1400G>A p.S467N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV61391087; called by muse, mutect2, varscan2
- NPHP3 | c.2989C>T p.Q997* | Nonsense Mutation (SNP) | VAF 26/86 reads (30%) | catalogued as COSV58632506; called by muse, mutect2, varscan2
- NYNRIN | c.3941G>A p.G1314D | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV66844284; called by muse, mutect2, varscan2
- OVOL2 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749206592, COSV53861640, COSV99602555; called by muse, mutect2
- PABPC5 | c.989G>T p.R330L | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV57039569, COSV57042673; called by muse, varscan2
- PHB | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as rs770266294, COSV55930744; called by muse, mutect2, varscan2
- PLCB2 | c.1857del p.M619Ifs*70 | Frame Shift Del (DEL) | VAF 26/76 reads (34%) | catalogued as COSV53036798; called by mutect2, pindel, varscan2
- PLEKHM3 | c.1816C>T p.Q606* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as COSV66818191; called by muse, mutect2, varscan2
- PLXNA2 | c.353T>C p.I118T | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV65443741; called by muse, mutect2, varscan2
- PPM1G | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59771109; called by muse, mutect2, varscan2
- PPP2R5E | c.808C>A p.P270T | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100518287, COSV61743667; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 160/438 reads (37%) | catalogued as rs146650273; called by pindel, varscan2
- RAB3IL1 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1262093530, COSV57118630; called by muse, mutect2, varscan2
- RBFOX2 | c.265G>A p.D89N (on ENST00000438146 / NM_001349995.2; = p.D19N on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 210/499 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as COSV53267293; called by muse, mutect2, varscan2
- RBL1 | c.2404C>T p.R802C | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771441987, COSV60332582; called by muse, mutect2, varscan2
- REV3L | c.900del p.K300Nfs*17 | Frame Shift Del (DEL) | VAF 100/252 reads (40%) | catalogued as COSV62621848; called by mutect2, varscan2
- RIN2 | c.893T>A p.V298E (on ENST00000255006 / NM_001242581.1; = p.V249E on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as COSV54792376; called by muse, mutect2
- RING1 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1204881780, COSV63002527; called by muse, mutect2, varscan2
- RMND5B | c.1118A>G p.K373R | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.163); catalogued as COSV51071234; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 27/90 reads (30%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RSBN1L | c.80G>A p.G27D | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); catalogued as COSV58508759; called by muse, mutect2, varscan2
- SASH1 | c.805C>G p.R269G | Missense Mutation (SNP) | VAF 81/201 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV66561194, COSV66564360; called by muse, mutect2, varscan2
- SCN1A | c.4630G>T p.D1544Y (on ENST00000303395 / NM_001202435.3; = p.D1533Y on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/221 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57682056; called by muse, mutect2, varscan2
- SCN1A | c.2152A>C p.S718R (on ENST00000303395 / NM_001202435.3; = p.S707R on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/233 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV57682074; called by muse, mutect2, varscan2
- SEZ6L2 | c.1237del p.L413Yfs*4 (on ENST00000308713 / NM_001114099.3; = p.L343Yfs*4 on NM_012410.4) | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as COSV58096751; called by mutect2, pindel
- SH3TC2 | c.3110T>C p.L1037P | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60466586; called by muse, mutect2, varscan2
- SLC18A1 | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 28/491 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs867015301, COSV52350548; called by muse, mutect2
- SLC41A3 | c.1451G>A p.C484Y | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV59989786; called by muse, mutect2, varscan2
- SMC1A | c.1756C>T p.R586W | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59128824; called by muse, mutect2, varscan2
- SNRK | c.1268C>T p.A423V | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs1559472589, COSV56070092; called by muse, mutect2, varscan2
- SNX6 | c.677G>A p.R226Q (on ENST00000652385; = p.R98Q on NM_021249.5) | Missense Mutation (SNP) | VAF 107/258 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as rs766507379, COSV61919725; called by muse, mutect2, varscan2
- SPIRE2 | c.1783G>A p.V595I | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs530541658, COSV65556813; called by muse, mutect2, varscan2
- SRSF1 | c.478G>A p.V160M | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV51966108; called by muse, mutect2
- SRSF6 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); catalogued as COSV54828654; called by muse, mutect2, varscan2
- STBD1 | c.713C>A p.T238N | Missense Mutation (SNP) | VAF 105/217 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.125); catalogued as COSV52954224; called by muse, mutect2, varscan2
- TAS2R38 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs1554444358, COSV71885895; called by muse, mutect2, varscan2
- TASOR2 | c.3674C>T p.S1225L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs1199796488, COSV60165314; called by muse, mutect2, varscan2
- TEX33 | c.593A>T p.Y198F (on ENST00000381821 / NM_001163857.2; = p.Y113F on NM_178552.4) | Missense Mutation (SNP) | VAF 8/187 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.204); catalogued as rs1373462312, COSV67822686; called by muse, mutect2
- TGFBR2 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.427); catalogued as rs727504292, CM054149, COSV55444676, COSV55450906; called by muse, mutect2, varscan2
- TMEM131 | c.433T>A p.S145T | Missense Mutation (SNP) | VAF 52/275 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51783344; called by muse, mutect2, varscan2
- TMEM176A | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.14); catalogued as COSV50244025; called by muse, mutect2, varscan2
- TMEM258 | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV53892488; called by muse, mutect2, varscan2
- TMEM71 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 102/442 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs147265782; called by muse, mutect2, varscan2
- TNNC1 | c.271G>T p.G91W | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV51768223; called by muse, mutect2, varscan2
- TRIM32 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs778141507, COSV57805916; called by muse, mutect2, varscan2
- TRIM69 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 58/145 reads (40%) | catalogued as rs200443297, COSV57804936; called by muse, mutect2, varscan2
- TRMT10C | c.393del p.K131Nfs*3 | Frame Shift Del (DEL) | VAF 36/74 reads (49%) | catalogued as rs760928888; called by mutect2, varscan2
- TSR2 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 179/425 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs376978451, COSV64309380; called by muse, mutect2, varscan2
- USP21 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.578); catalogued as rs776184092, COSV57090523; called by muse, mutect2, varscan2
- USP32 | c.2124T>A p.S708R | Missense Mutation (SNP) | VAF 152/342 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV56274691; called by muse, mutect2, varscan2
- USP35 | c.1962del p.T655Pfs*23 | Frame Shift Del (DEL) | VAF 98/268 reads (37%) | catalogued as rs764735138; called by mutect2, varscan2
- VPS8 | c.635C>T p.S212L (on ENST00000625842 / NM_001349294.1; = p.S210L on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/235 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as rs770686589, COSV54993523, COSV99802338; called by muse, mutect2, varscan2
- WASHC2C | c.773G>A p.G258D | Missense Mutation (SNP) | VAF 286/694 reads (41%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.622); catalogued as COSV60493104; called by muse, mutect2, varscan2
- YTHDF3 | c.902T>C p.I301T | Missense Mutation (SNP) | VAF 114/448 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV72773790; called by muse, varscan2
- ZFHX4 | c.4141C>T p.Q1381* | Nonsense Mutation (SNP) | VAF 168/688 reads (24%) | catalogued as COSV51486212, COSV99259970; called by muse, mutect2, varscan2
- ZNF208 | c.2317G>A p.V773I | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs558490237, COSV68110983; called by muse, mutect2, varscan2
- ZNF521 | c.2681C>T p.A894V | Missense Mutation (SNP) | VAF 143/310 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV64130477; called by muse, mutect2, varscan2
- ZNF766 | c.490C>G p.H164D | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV63010071; called by muse, mutect2, varscan2
- CFAP299 | c.675del p.F225Lfs*21 | Frame Shift Del (DEL) | VAF 74/205 reads (36%) | called by mutect2, pindel, varscan2
- CREBBP | c.5238dup p.L1747Afs*5 | Frame Shift Ins (INS) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- DPP4 | c.1377_1378del p.S460Ifs*3 | Frame Shift Del (DEL) | VAF 122/314 reads (39%) | called by pindel, varscan2
- FEZF1 | c.1088dup p.L364Vfs*51 | Frame Shift Ins (INS) | VAF 48/142 reads (34%) | called by mutect2, pindel, varscan2
- GPR84 | c.1048dup p.V350Gfs*45 | Frame Shift Ins (INS) | VAF 20/61 reads (33%) | called by mutect2, pindel, varscan2
- IRF2BP2 | c.1522C>T p.L508F | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by mutect2, varscan2
- MEGF8 | c.3392del p.P1131Rfs*9 (on ENST00000251268 / NM_001271938.2; = p.P1064Rfs*9 on NM_001410.3) | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | called by mutect2, pindel, varscan2
- MGRN1 | c.1080del p.K360Nfs*138 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | called by mutect2, pindel, varscan2
- NIPBL | c.5599del p.R1867Efs*2 | Frame Shift Del (DEL) | VAF 80/200 reads (40%) | called by mutect2, pindel, varscan2
- OR10H4 | c.591_596del p.I198_M199del | In Frame Del (DEL) | VAF 195/513 reads (38%) | called by mutect2, pindel, varscan2
- SH2B3 | c.1566del p.E523Sfs*25 | Frame Shift Del (DEL) | VAF 35/106 reads (33%) | called by mutect2, pindel, varscan2
- USP12 | c.528del p.Q177Rfs*4 | Frame Shift Del (DEL) | VAF 197/535 reads (37%) | called by mutect2, pindel, varscan2
- WDFY2 | c.228del p.F76Lfs*10 | Frame Shift Del (DEL) | VAF 109/390 reads (28%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.7171del p.L2391* | Frame Shift Del (DEL) | VAF 34/167 reads (20%) | called by mutect2, pindel, varscan2
- ACADVL | c.294G>A p.Q98= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as rs794727695, COSV50034513, COSV50038489; called by muse, mutect2, varscan2
- ADAMTS9 | c.3402C>T p.C1134= | Silent (SNP) | VAF 74/184 reads (40%) | catalogued as COSV55787618; called by muse, mutect2, varscan2
- ADSL | c.1422C>T p.S474= | Silent (SNP) | VAF 60/691 reads (9%) | catalogued as rs748593655, COSV50651472; ClinVar: likely benign; called by muse, mutect2
- ANGPTL5 | c.1086G>A p.T362= | Silent (SNP) | VAF 162/374 reads (43%) | catalogued as rs373076823; called by muse, mutect2, varscan2
- ARFGEF1 | c.408C>T p.G136= | Silent (SNP) | VAF 103/510 reads (20%) | catalogued as COSV51615005; called by muse, mutect2, varscan2
- ATAD5 | c.1743T>C p.S581= | Silent (SNP) | VAF 38/110 reads (35%) | catalogued as COSV58977597; called by muse, mutect2, varscan2
- ATP8B1 | c.1134C>T p.D378= | Silent (SNP) | VAF 56/141 reads (40%) | catalogued as rs554968809, COSV52178928; called by muse, mutect2, varscan2
- CABS1 | c.264A>G p.S88= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV56734310; called by muse, mutect2, varscan2
- CACNA1E | c.2979C>T p.S993= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as rs752775710, COSV62401375; called by muse, mutect2, varscan2
- CANX | c.1566G>A p.P522= | Silent (SNP) | VAF 147/315 reads (47%) | catalogued as rs755647285, COSV56004987; called by muse, mutect2, varscan2
- CHRNB1 | c.981C>T p.V327= | Silent (SNP) | VAF 88/197 reads (45%) | catalogued as rs1195435380, COSV60141784; called by muse, mutect2, varscan2
- CLCN5 | c.2076C>T p.D692= | Silent (SNP) | VAF 175/408 reads (43%) | catalogued as COSV56586060; called by muse, mutect2, varscan2
- CLIC6 | c.1461C>T p.C487= (on ENST00000360731 / NM_001317009.2; = p.C469= on NM_053277.3) | Silent (SNP) | VAF 17/506 reads (3%) | catalogued as rs1490701659, COSV62448899; called by muse, mutect2
- DNAJC6 | c.2139G>A p.A713= | Silent (SNP) | VAF 42/81 reads (52%) | catalogued as rs113490907; ClinVar: likely benign; called by muse, mutect2, varscan2
- FARSB | c.852C>A p.V284= | Silent (SNP) | VAF 148/318 reads (47%) | catalogued as COSV56051816; called by muse, mutect2, varscan2
- GNLY | c.129C>T p.C43= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV55704409; called by muse, mutect2, varscan2
- IGF2BP3 | c.906T>C p.I302= | Silent (SNP) | VAF 314/727 reads (43%) | catalogued as COSV51682528, COSV51690817; called by muse, mutect2, varscan2
- IGHM | c.1239C>T p.C413= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs199679674; called by muse, mutect2, varscan2
- ITPR2 | c.4827A>T p.V1609= | Silent (SNP) | VAF 63/122 reads (52%) | catalogued as COSV67274446; called by muse, mutect2, varscan2
- KIF1C | c.2109G>A p.T703= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs372267137; ClinVar: likely benign; called by muse, mutect2, varscan2
- KRT77 | c.1596C>A p.G532= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV59241021; called by muse, mutect2, varscan2
- MAOB | c.1245C>A p.R415= | Silent (SNP) | VAF 66/193 reads (34%) | catalogued as rs778022016, COSV65206478; called by muse, mutect2, varscan2
- MYH7 | c.3901C>T p.L1301= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as COSV62522417; called by muse, mutect2, varscan2
- PCDHB5 | c.1551G>A p.S517= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as rs1450169772, COSV50662826; called by muse, mutect2, varscan2
- PRAMEF12 | c.921G>A p.S307= | Silent (SNP) | VAF 54/128 reads (42%) | catalogued as rs374440616, COSV100743238; called by muse, mutect2, varscan2
- RASAL2 | c.183C>T p.D61= | Silent (SNP) | VAF 107/333 reads (32%) | catalogued as COSV62720229; called by muse, mutect2, varscan2
- SAXO1 | c.531C>T p.Y177= | Silent (SNP) | VAF 148/364 reads (41%) | catalogued as rs767381951, COSV65871453; called by muse, mutect2, varscan2
- SHOC1 | c.4311G>A p.G1437= | Silent (SNP) | VAF 130/295 reads (44%) | catalogued as COSV59505954; called by muse, mutect2, varscan2
- SLC19A3 | c.289C>T p.L97= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as COSV51454306; called by muse, mutect2, varscan2
- ST8SIA2 | c.1125G>A p.T375= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs765333385, COSV51567047, COSV51571921; called by muse, mutect2, varscan2
- TENT4A | c.1764C>A p.P588= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as COSV50095798, COSV50098552; called by muse, mutect2, varscan2
- TGS1 | c.2160C>T p.I720= | Silent (SNP) | VAF 122/533 reads (23%) | catalogued as rs368766097; called by muse, mutect2, varscan2
- TNXB | c.4512G>A p.E1504= (on ENST00000647633; = p.E1257= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as COSV64486203; called by muse, mutect2, varscan2
- UBAP2 | c.3102G>A p.G1034= | Silent (SNP) | VAF 61/140 reads (44%) | catalogued as COSV54291975; called by muse, mutect2, varscan2
- UMOD | c.1902C>A p.T634= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs766780246, COSV56778560; called by muse, mutect2, varscan2
- COPA | c.1529-20A>G | Intron (SNP) | VAF 28/358 reads (8%) | catalogued as COSV99615359; called by muse, mutect2
